CCDI case PBCMHI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3dd4f3f6-5a31-4377-85e2-14967e687402

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,345 days).

Biospecimens (3 samples)
- Sample 0DVXF2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVXFF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVXFM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
